MMRF case MMRF_2174 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/01489f5a-650e-4e15-aacf-a8463cbed03c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 85 years; Vital status: Dead; Days to death: 425 days (1.2 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 85.5 years (31,241 days); Days to last known disease status: 425 days (1.2 years); Days to last follow up: 425 days (1.2 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 4 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 6 days; Days to treatment end: 250 days.
   Treatment given: Therapeutic agents: Melphalan + Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 6 days; Days to treatment end: 145 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 146 days; Days to treatment end: 250 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 146 days; Days to treatment end: 201 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 202 days; Days to treatment end: 250 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 425.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 3): M Protein 6.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 338 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.7 mg/dL; Hemoglobin 6.01 mmol/L; Leukocytes 3.79 ×10⁹/L; Absolute Neutrophil 1.63 ×10⁹/L; Platelets 101 ×10⁹/L; Creatinine 778 µmol/L; Albumin 30 g/L; Total Protein 5.7 g/dL.
- Day 82 (ECOG 3): M Protein 2.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 423 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.08 mg/dL; Immunoglobulin G 8.2 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 6.32 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.19 ×10⁹/L; Platelets 127 ×10⁹/L; Creatinine 638 µmol/L; Calcium 2.15 mmol/L; Albumin 32 g/L; Total Protein 5.5 g/dL; Glucose 7.4 mmol/L.
- Day 180 (ECOG 3): M Protein 2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 368 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.75 mg/dL; Immunoglobulin G 4.8 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 5.52 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1.46 ×10⁹/L; Platelets 133 ×10⁹/L; Creatinine 765 µmol/L; Albumin 34 g/L; Total Protein 5.6 g/dL; Glucose 11.5 mmol/L.
- Day 278 (ECOG 2): M Protein 2.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 517 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.83 mg/dL; Immunoglobulin G 6.4 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 6.01 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.48 ×10⁹/L; Platelets 87 ×10⁹/L; Creatinine 498 µmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 6.2 g/dL; Glucose 9 mmol/L.
- Day 376 (ECOG 2): M Protein 3.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 914 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.03 mg/dL; Immunoglobulin G 7.6 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 4.84 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 623 µmol/L; Calcium 2.22 mmol/L; Albumin 34 g/L; Total Protein 6.2 g/dL; Glucose 10.8 mmol/L.

Other clinical attributes
- Day 1: Weight: 79 kg; Height: 180 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_2174_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2174_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
